Somatic mutation profile of tumor specimen ALCH-B4QA-TTP1-A (aliquot ALCH-B4QA-TTP1-A-2-0-D-A81V-36) from ALCHEMIST case ALCH-B4QA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.9 years (22,982 days).
Specimen ALCH-B4QA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6993a72-cb89-433b-a4b7-35c727decc0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4QA-NB1-A (Blood Derived Normal), aliquot ALCH-B4QA-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c7e3b6b-6030-4f9e-b4d6-535ca4c25221

The open-access MAF lists 138 somatic variants for this specimen: 102 protein-altering or splice-affecting, 24 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 24, Nonsense Mutation 12, Intron 8, Splice Region 4, Splice Site 3, RNA 2, Frame Shift Del 1, In Frame Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 64/574 reads (11%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- IDH1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 34/318 reads (11%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.1837G>T p.E613* (on ENST00000373394 / NM_001271696.3; = p.E614* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 12/380 reads (3%) | catalogued as COSV99504775; called by muse, mutect2
- ADGRB1 | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs577805420, COSV60100189; called by muse, mutect2
- ARFGEF3 | c.5314G>T p.D1772Y | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76821867, COSV52471305; called by muse, mutect2
- ATP10D | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs778615439; called by muse, mutect2, varscan2
- CCDC178 | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV55777405; called by muse, mutect2, varscan2
- CDKL5 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 81/754 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1241585738; called by muse, mutect2, varscan2
- CNGA3 | c.1036G>T p.G346W | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs775262372; called by muse, mutect2
- CSMD2 | c.9604G>T p.G3202W | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53898224, COSV53926649; called by muse, mutect2, varscan2
- DMD | c.5750G>C p.R1917P | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.548); catalogued as COSV63773645; called by muse, mutect2, varscan2
- FCRL3 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs746762170; called by muse, mutect2
- FLG | c.11681A>C p.Q3894P | Missense Mutation (SNP) | VAF 40/674 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs1186043871; called by muse, mutect2
- GFOD1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs777267857; called by muse, mutect2
- HOXA2 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 47/461 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56065933; called by muse, mutect2, varscan2
- IFNL1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769258923, COSV61318091; called by muse, mutect2, varscan2
- KLRC4 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.735); catalogued as COSV100511335; called by muse, mutect2, varscan2
- MAGEC1 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.076); catalogued as rs1212577822; called by muse, mutect2, varscan2
- MRPL55 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs775022732, COSV54341846; called by muse, mutect2, varscan2
- MUC17 | c.4262T>C p.V1421A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs185024900; called by muse, mutect2, varscan2
- MYH13 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749296856, COSV99356134; called by muse, mutect2
- PCDHGA2 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.262); catalogued as rs1341781160, COSV99535516; called by muse, mutect2
- PEG3 | c.3436C>T p.H1146Y | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV55626998; called by muse, mutect2, varscan2
- PRRG1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1556388251, COSV101069043; called by muse, mutect2
- QRICH2 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs942250324; called by muse, mutect2
- RAB11FIP5 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV50247738; called by muse, varscan2
- RTCB | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs752210819, COSV53279400; called by muse, mutect2
- STPG2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99762080; called by muse, mutect2, varscan2
- SYN1 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.056); catalogued as rs909332243; called by muse, mutect2
- ZNF799 | c.1133C>G p.S378* | Nonsense Mutation (SNP) | VAF 15/612 reads (2%) | catalogued as rs1478713880; called by muse, mutect2
- ZNF823 | c.947A>T p.H316L (on ENST00000341191 / NM_001297610.2; = p.H272L on NM_017507.2) | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57874455; called by muse, mutect2
- ADAMTS13 | c.2273G>T p.C758F | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ANKRD24 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP7A | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 54/503 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C14orf39 | c.1628C>A p.T543N | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2
- C2orf74 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CASTOR2 | c.867G>C p.L289F | Missense Mutation (SNP) | VAF 59/520 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CCDC60 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFAP61 | c.-37+4G>T | Splice Region (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- CLEC4F | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- COL5A2 | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 76/773 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL5A3 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL6A3 | c.4720G>T p.G1574* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2
- CYP3A7 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2
- CYTH3 | c.460T>C p.W154R | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DCHS1 | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- FAF2 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM47B | c.1925C>G p.S642* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | called by mutect2, varscan2
- FAT3 | c.9200C>A p.S3067* | Nonsense Mutation (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- FLG | c.2858_2860delinsT p.E953Vfs*7 | Frame Shift Del (DEL) | VAF 70/681 reads (10%) | called by pindel, varscan2*
- G2E3 | c.635+2_635+3del p.X212_splice | Splice Site (DEL) | VAF 23/244 reads (9%) | called by mutect2, pindel
- GABRA5 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 47/448 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRA5 | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GFPT2 | c.1907T>C p.I636T | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- GOLGA6L2 | c.1846G>A p.G616R | Missense Mutation (SNP) | VAF 40/711 reads (6%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2
- GRK7 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- HEMGN | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 34/704 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- IFNA14 | c.545A>C p.Q182P | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); called by muse, mutect2
- KALRN | c.8783C>A p.T2928K (on ENST00000360013 / NM_001024660.4; = p.T1231K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/351 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KAT2B | c.819T>A p.D273E | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.034); called by muse, mutect2
- KCTD2 | c.623G>T p.W208L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.389); called by muse, mutect2
- KCTD2 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- KYNU | c.1313T>A p.V438D | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- LDOC1 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 47/566 reads (8%) | called by muse, mutect2
- LRP11 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRFIP1 | c.1680G>C p.E560D | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LYST | c.5614G>T p.V1872F | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBNL1 | c.1015+2dup p.X339_splice (on ENST00000282486 / NM_207293.2; = p.X321_splice on NM_021038.5 and 10 other RefSeq transcripts) | Splice Site (INS) | VAF 19/156 reads (12%) | called by mutect2, pindel
- MTMR1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- MUC5AC | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.26); called by muse, mutect2
- MYH13 | c.2330T>C p.L777S | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- NALCN | c.2194G>T p.A732S | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCAN | c.2225A>C p.E742A | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NTRK3 | c.1787A>T p.Q596L | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NTRK3 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- OPN5 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OPN5 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); called by muse, mutect2
- OR13C8 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PCDHGA1 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); called by muse, mutect2
- PCYT1B | c.944C>A p.S315Y | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- PDE3A | c.2002-1G>T p.X668_splice | Splice Site (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- PKNOX2 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | called by muse, mutect2, varscan2
- POLN | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- POU4F2 | c.4A>T p.M2L | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by mutect2, varscan2
- PP2D1 | c.644C>G p.A215G | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRT2 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PYROXD2 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2
- RNF135 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 81/434 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SHANK1 | c.937A>T p.N313Y | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHKBP1 | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC17A6 | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- STAR | c.179-4C>T | Splice Region (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- STAR | c.179-6A>T | Splice Region (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- TBC1D8B | c.2890C>A p.Q964K | Missense Mutation (SNP) | VAF 40/598 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.65); called by muse, mutect2
- TBL1X | c.894C>A p.T298= | Splice Region (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- TDG | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 23/443 reads (5%) | called by muse, mutect2
- TRIM49 | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 51/523 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- WAS | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- WDSUB1 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2
- ZNF415 | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.294); called by muse, mutect2
- ZNF644 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.025); called by muse, mutect2
- ZNF7 | c.1639C>A p.H547N | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCA13 | c.5635C>A p.R1879= | Silent (SNP) | VAF 61/246 reads (25%) | called by muse, mutect2, varscan2
- CCDC85C | c.150C>T p.G50= | Silent (SNP) | VAF 38/294 reads (13%) | catalogued as rs1290816752; called by muse, mutect2, varscan2
- CD300A | c.414G>C p.A138= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV60409917, COSV60410568; called by muse, mutect2, varscan2
- CFAP45 | c.1296G>A p.E432= | Silent (SNP) | VAF 23/593 reads (4%) | called by muse, mutect2
- CLIP1 | c.1323T>C p.L441= | Silent (SNP) | VAF 37/337 reads (11%) | called by muse, mutect2, varscan2
- CXCR1 | c.684A>G p.T228= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as rs749000335; called by muse, mutect2, varscan2
- DAPP1 | c.513C>A p.L171= | Silent (SNP) | VAF 56/532 reads (11%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.57C>T p.D19= | Silent (SNP) | VAF 26/324 reads (8%) | catalogued as COSV64422675; called by muse, mutect2
- GPR45 | c.408C>T p.I136= | Silent (SNP) | VAF 48/361 reads (13%) | catalogued as rs770278854; called by muse, mutect2, varscan2
- IQSEC2 | c.2533C>A p.R845= (on ENST00000642864 / NM_001111125.3; = p.R640= on NM_015075.2) | Silent (SNP) | VAF 38/342 reads (11%) | called by muse, mutect2, varscan2
- KLRC4 | c.318C>A p.S106= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as COSV58672394; called by muse, mutect2, varscan2
- LOXL1 | c.1386C>T p.D462= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- LRRTM1 | c.598C>T p.L200= | Silent (SNP) | VAF 8/230 reads (3%) | called by muse, mutect2
- PCYT1B | c.945C>A p.S315= | Silent (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- POLQ | c.3618T>A p.T1206= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- PRDM14 | c.1330C>A p.R444= | Silent (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- RAPGEF1 | c.1899G>T p.A633= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs549201601, COSV100940307; called by muse, mutect2
- RCSD1 | c.480G>T p.R160= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- SFTPB | c.531C>T p.V177= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as rs751001412, COSV60892872; called by muse, mutect2, varscan2
- SLC1A3 | c.825C>T p.N275= | Silent (SNP) | VAF 17/190 reads (9%) | catalogued as rs201765665, COSV54318632; ClinVar: uncertain significance; called by muse, mutect2
- SV2A | c.682C>A p.R228= | Silent (SNP) | VAF 12/238 reads (5%) | catalogued as COSV64965542; called by muse, mutect2
- VPS13C | c.7029G>A p.V2343= (on ENST00000644861 / NM_020821.3; = p.V2300= on NM_017684.5) | Silent (SNP) | VAF 15/564 reads (3%) | called by muse, mutect2
- ZNF208 | c.30C>A p.A10= | Silent (SNP) | VAF 40/390 reads (10%) | catalogued as COSV68106598; called by muse, mutect2, varscan2
- ZNF594 | c.1788T>C p.Y596= | Silent (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- ERBB3 | c.732+21C>T | Intron (SNP) | VAF 23/176 reads (13%) | catalogued as rs1565857361; called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010154 G>T | 5'Flank (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- FLNA | c.6907+30G>A | Intron (SNP) | VAF 40/358 reads (11%) | called by muse, mutect2, varscan2
- FMO6P | n.639A>T | RNA (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- HSD17B4 | c.815-47G>C | Intron (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- MAPK3 | c.171-10G>A | Intron (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- MIR323A | n.30G>A | RNA (SNP) | VAF 14/198 reads (7%) | catalogued as rs903273613; called by muse, mutect2
- MOGAT3 | c.872-24C>G | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- NLRP2 | c.*45G>T | 3'UTR (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2
- PKP4 | c.132+133C>T | Intron (SNP) | VAF 40/442 reads (9%) | called by muse, mutect2
- RBFOX1 | c.996-15694C>T | Intron (SNP) | VAF 20/292 reads (7%) | catalogued as COSV60979799; called by muse, mutect2
- ZNF605 | c.136+322G>A | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2
